Somatic mutation profile of tumor specimen TCGA-DK-AA6W-01A (aliquot TCGA-DK-AA6W-01A-12D-A391-08) from TCGA case TCGA-DK-AA6W, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 79.0 years (28,853 days).
Specimen TCGA-DK-AA6W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f0d2d70-59a4-48d8-8c47-5bcc2daf772a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA6W-10A (Blood Derived Normal), aliquot TCGA-DK-AA6W-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ad31858-36bc-4870-977e-12e531a6e6d3

The open-access MAF lists 281 somatic variants for this specimen: 198 protein-altering or splice-affecting, 72 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 167, Silent 72, Nonsense Mutation 20, Splice Site 6, Intron 5, RNA 5, Frame Shift Del 4, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.636del p.R213Dfs*34 | Frame Shift Del (DEL) | VAF 34/53 reads (64%) | catalogued as rs864309495, CD011205, COSV52729299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCB11 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV55585499; called by muse, mutect2, varscan2
- ABHD2 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 84/116 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1442155248, COSV61772857; called by muse, mutect2, varscan2
- ACAD10 | c.637G>A p.D213N | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV58154030; called by muse, mutect2, varscan2
- ACAN | c.2059G>C p.E687Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV100717535; called by muse, mutect2
- ACSM4 | c.1701C>G p.I567M | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1192675611, COSV68066663; called by muse, mutect2, varscan2
- ACTG1 | c.786C>A p.F262L | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV59509670; called by muse, mutect2, varscan2
- ADAMTS2 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as rs750197805, COSV51072125; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4754+2T>G p.X1585_splice | Splice Site (SNP) | VAF 33/106 reads (31%) | catalogued as COSV54436418; called by muse, mutect2, varscan2
- ADGRE2 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs200783500; called by muse, mutect2, varscan2
- AFDN | c.1391G>C p.R464T | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs1225312189, COSV60037774; called by muse, mutect2, varscan2
- AGAP3 | c.687G>C p.E229D (on ENST00000622464; = p.E265D on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58993457; called by muse, mutect2, varscan2
- AKAP9 | c.6102G>C p.M2034I (on ENST00000359028; = p.M2002I on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62338766; called by muse, mutect2, varscan2
- ALMS1 | c.8780G>A p.R2927Q | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.095); catalogued as rs778162209, COSV52502867; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALX1 | c.195G>C p.L65F | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.076); catalogued as COSV57491188, COSV57493002; called by muse, mutect2, varscan2
- ANKFY1 | c.3226C>T p.Q1076* (on ENST00000341657 / NM_001330063.2; = p.Q1077* on NM_016376.5) | Nonsense Mutation (SNP) | VAF 52/59 reads (88%) | catalogued as COSV100492443; called by muse, mutect2, varscan2
- ANKMY1 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201979948, COSV56030158; called by muse, mutect2, varscan2
- ANKRD11 | c.3469G>C p.E1157Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); catalogued as COSV56354852, COSV56358780; called by muse, mutect2, varscan2
- ANKRD11 | c.3022G>C p.E1008Q | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as COSV56354860; called by muse, mutect2, varscan2
- ANKRD11 | c.2773G>T p.E925* | Nonsense Mutation (SNP) | VAF 44/88 reads (50%) | catalogued as COSV56361725, COSV99968780; called by muse, mutect2, varscan2
- ARHGAP22 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.162); catalogued as COSV50932676, COSV99985301; called by muse, mutect2, varscan2
- ARHGAP39 | c.2699G>C p.R900T (on ENST00000276826 / NM_001308208.2; = p.R931T on NM_025251.2) | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV52767003; called by muse, mutect2, varscan2
- ARHGAP45 | c.3300C>G p.F1100L | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.01); catalogued as COSV53123325; called by muse, mutect2, varscan2
- ARID1A | c.2132C>G p.S711* | Nonsense Mutation (SNP) | VAF 25/40 reads (63%) | catalogued as COSV61376007; called by muse, varscan2
- ATG12 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.289); catalogued as COSV57242655; called by muse, varscan2
- BPIFA3 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.349); catalogued as rs750803835, COSV64925581; called by muse, mutect2, varscan2
- BRMS1 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs564172836, COSV60819651; called by muse, mutect2, varscan2
- CALD1 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as rs1224167001, COSV62645149; called by muse, mutect2, varscan2
- CANX | c.335C>G p.S112* | Nonsense Mutation (SNP) | VAF 28/86 reads (33%) | catalogued as COSV99910329; called by muse, mutect2, varscan2
- CASP2 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as COSV60081396; called by muse, mutect2, varscan2
- CCAR2 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 82/235 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.605); catalogued as COSV51514438; called by muse, mutect2, varscan2
- CCDC181 | c.462C>G p.F154L | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63155689; called by muse, mutect2, varscan2
- CCDC30 | c.730G>C p.E244Q (on ENST00000340612; = p.E201Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs376480393, COSV59604377; called by muse, mutect2, varscan2
- CD44 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV53528126; called by muse, mutect2, varscan2
- CDHR5 | c.2452G>A p.E818K (on ENST00000358353 / NM_001171968.2; = p.E824K on NM_021924.5) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as rs1393278064, COSV57642332, COSV57642954; called by muse, mutect2
- CENPH | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV51584189; called by muse, mutect2, varscan2
- CENPU | c.97-1G>A p.X33_splice | Splice Site (SNP) | VAF 3/28 reads (11%) | catalogued as COSV99859820; called by muse, mutect2
- CEP170B | c.2604G>C p.E868D (on ENST00000453495; = p.E797D on NM_015005.3) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.101); catalogued as rs991318322, COSV69023238; called by muse, mutect2, varscan2
- CHPF2 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV50389038; called by muse, mutect2, varscan2
- CHRM3 | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as rs774998249, COSV55080383; called by muse, mutect2, varscan2
- CIP2A | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV55417154; called by muse, mutect2, varscan2
- CLIP1 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV56797409; called by muse, mutect2, varscan2
- COL4A3 | c.4856G>T p.R1619I | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67412810, COSV67416099; called by muse, mutect2, varscan2
- COMMD5 | c.186G>C p.E62D | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV57382631; called by muse, mutect2, varscan2
- CTBP2 | c.895G>C p.E299Q | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as COSV58332540; called by muse, mutect2, varscan2
- CTNNA2 | c.1259T>A p.V420D | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs1263495673, COSV100560060, COSV58135013, COSV58149761; called by muse, mutect2, varscan2
- CTNND2 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs1445784718, COSV58865546; called by muse, mutect2, varscan2
- CTSF | c.1188G>C p.K396N | Missense Mutation (SNP) | VAF 24/27 reads (89%) | SIFT tolerated (0.07); PolyPhen benign (0.35); catalogued as COSV59747461; called by muse, mutect2, varscan2
- CTSF | c.1164G>C p.Q388H | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT tolerated (0.14); PolyPhen benign (0.357); catalogued as COSV59747479; called by muse, mutect2, varscan2
- CYP4X1 | c.320-1G>T p.X107_splice | Splice Site (SNP) | VAF 45/182 reads (25%) | catalogued as COSV64149649; called by muse, varscan2
- CYP4X1 | c.840G>C p.K280N | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV64149665; called by muse, mutect2, varscan2
- DEPDC5 | c.722C>G p.S241* | Nonsense Mutation (SNP) | VAF 92/109 reads (84%) | catalogued as COSV99834831; called by muse, mutect2, varscan2
- DNAJB2 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773941610, COSV99833831; called by muse, varscan2
- DNMT3B | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.384); catalogued as COSV52414996; called by muse, mutect2, varscan2
- DOCK4 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 57/188 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.718); catalogued as COSV70314638; called by muse, mutect2, varscan2
- DOP1B | c.6856G>T p.E2286* | Nonsense Mutation (SNP) | VAF 12/140 reads (9%) | catalogued as COSV67690828; called by muse, mutect2
- DPP10 | c.1361+1G>T p.X454_splice | Splice Site (SNP) | VAF 20/58 reads (34%) | catalogued as rs1227063662, COSV59664914; called by muse, mutect2, varscan2
- DSP | c.6250C>T p.Q2084* | Nonsense Mutation (SNP) | VAF 49/181 reads (27%) | catalogued as COSV101131208; called by muse, mutect2, varscan2
- DUXA | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as COSV73729493; called by muse, mutect2, varscan2
- EEF2K | c.1861G>A p.D621N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV53778587; called by muse, mutect2, varscan2
- EP300 | c.4570G>A p.E1524K | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54326530; called by muse, mutect2, varscan2
- EPPK1 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); catalogued as COSV73260808; called by muse, mutect2, varscan2
- EPS8L3 | c.320C>G p.S107C | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62608749; called by muse, mutect2, varscan2
- FAM111A | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64655027; called by muse, mutect2, varscan2
- FAM135A | c.4063C>G p.L1355V (on ENST00000370479 / NM_001351599.1; = p.L1142V on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52047751, COSV52051624; called by muse, mutect2, varscan2
- FAM13A | c.3047G>C p.R1016T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51996804; called by muse, mutect2, varscan2
- FAM219A | c.161-1G>C p.X54_splice (on ENST00000445726; = p.X37_splice on NM_147202.2 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 20/27 reads (74%) | catalogued as COSV52619504; called by muse, mutect2, varscan2
- FDXACB1 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs782147764, COSV52786349; called by muse, varscan2
- FLG2 | c.6900G>C p.Q2300H | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as COSV101165958, COSV66166669; called by muse, mutect2, varscan2
- FNDC7 | c.1035C>A p.F345L | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV54750713; called by muse, mutect2, varscan2
- FOXA3 | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 24/104 reads (23%) | catalogued as COSV100141297; called by muse, mutect2, varscan2
- FREM2 | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 34/44 reads (77%) | catalogued as COSV99747775; called by muse, mutect2, varscan2
- FURIN | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs754366900, COSV51574462; called by muse, mutect2, varscan2
- GABBR2 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.367); catalogued as rs76761930; ClinVar: likely benign; called by muse, mutect2, varscan2
- GEMIN4 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 58/75 reads (77%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1270570544, COSV56744881; called by muse, mutect2, varscan2
- GFPT2 | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53806412, COSV53811860; called by muse, mutect2
- GIGYF2 | c.1541C>G p.S514* | Nonsense Mutation (SNP) | VAF 48/101 reads (48%) | catalogued as COSV101004178, COSV65252848; called by muse, mutect2, varscan2
- GIPC3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs754854408, COSV59258270; called by muse, varscan2
- GPC5 | c.908C>G p.S303W | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65577492, COSV65583949; called by muse, mutect2, varscan2
- GRIA1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs759117420, COSV53589188; called by muse, mutect2, varscan2
- GUCY2D | c.1123G>A p.G375R | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs773811368, COSV54694460; called by muse, mutect2, varscan2
- HERC2 | c.6099C>G p.I2033M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV55307760; called by muse, mutect2, varscan2
- HTATSF1 | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 127/176 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54477365, COSV99511853; called by muse, mutect2, varscan2
- INHBE | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99875247; called by muse, mutect2
- IQSEC2 | c.3007C>G p.L1003V (on ENST00000642864 / NM_001111125.3; = p.L798V on NM_015075.2) | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV64723587; called by muse, mutect2, varscan2
- IRF2 | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101165867, COSV66928529, COSV66929484; called by muse, mutect2
- ITPRIPL1 | c.1088C>G p.S363* (on ENST00000439118 / NM_001008949.3; = p.S371* on NM_178495.6) | Nonsense Mutation (SNP) | VAF 39/154 reads (25%) | catalogued as rs199538607, COSV100742171; called by muse, mutect2, varscan2
- KCNIP3 | c.370C>G p.Q124E | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV54665873; called by muse, mutect2, varscan2
- KCNJ10 | c.883C>G p.Q295E | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63632846; called by muse, varscan2
- KCNV1 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV52084649; called by muse, mutect2, varscan2
- KDM6A | c.1580_1587del p.P527Rfs*23 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as COSV65037194; called by mutect2, varscan2
- KIAA1614 | c.278_280del p.K93del | In Frame Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs1414154753; called by pindel, varscan2
- KLHL1 | c.1130A>G p.H377R | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as rs1207101558, COSV64767144; called by muse, mutect2, varscan2
- KLHL1 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as COSV64767146; called by muse, mutect2, varscan2
- KNL1 | c.3362A>G p.E1121G (on ENST00000346991 / NM_170589.5; = p.E1095G on NM_144508.5) | Missense Mutation (SNP) | VAF 44/55 reads (80%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV61151123; called by muse, mutect2, varscan2
- LCE1E | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.035); catalogued as COSV64219514; called by muse, varscan2
- LCK | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1557585028, COSV60738593; called by muse, mutect2, varscan2
- LCOR | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV53714375; called by muse, mutect2, varscan2
- LIMK1 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 73/132 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs782664768, COSV60279952; called by muse, mutect2, varscan2
- LRFN5 | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53243425; called by muse, mutect2, varscan2
- LRP1 | c.1017C>G p.F339L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV54502095; called by muse, mutect2, varscan2
- LRP8 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs768118431, COSV60096113; called by muse, mutect2, varscan2
- LRRC7 | c.1519G>A p.D507N (on ENST00000651989 / NM_001370785.2; = p.D474N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs757125340, COSV50411187, COSV99229278; called by muse, mutect2, varscan2
- LYST | c.653C>A p.A218D | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV67703322; called by muse, mutect2, varscan2
- MAG | c.1523G>A p.R508Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as COSV100727540, COSV62698993; called by muse, mutect2, varscan2
- MAP4K1 | c.307T>A p.Y103N | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50263712; called by muse, mutect2, varscan2
- MARCHF7 | c.1217G>C p.R406T | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52027474; called by muse, mutect2, varscan2
- MCCC1 | c.1597C>G p.Q533E | Missense Mutation (SNP) | VAF 365/444 reads (82%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as COSV55606344, COSV99659898; called by muse, mutect2, varscan2
- MCM10 | c.2125G>A p.E709K (on ENST00000484800 / NM_182751.3; = p.E708K on NM_018518.5) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.294); catalogued as COSV66333072; called by muse, mutect2, varscan2
- MET | c.2815G>T p.V939F | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV59256917; called by muse, mutect2, varscan2
- MST1R | c.2626G>A p.E876K | Missense Mutation (SNP) | VAF 47/58 reads (81%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.913); catalogued as COSV56564606; called by muse, mutect2, varscan2
- MTDH | c.1232C>A p.S411* | Nonsense Mutation (SNP) | VAF 39/294 reads (13%) | catalogued as COSV100292438; called by muse, mutect2, varscan2
- MYH10 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52595093; called by muse, mutect2, varscan2
- MYO16 | c.5501A>C p.K1834T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV62745469, COSV62749614; called by muse, mutect2, varscan2
- MYO1H | c.1076G>C p.R359T | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60443020; called by muse, mutect2, varscan2
- MYT1L | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV67708393, COSV67730939; called by muse, mutect2, varscan2
- NAV2 | c.7387C>T p.P2463S (on ENST00000396087 / NM_001244963.2; = p.P2404S on NM_145117.5) | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV60656473; called by muse, mutect2, varscan2
- NBN | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV55371202; called by muse, mutect2, varscan2
- NF1 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV62193190, COSV62197881; called by muse, mutect2, varscan2
- NHLRC1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 152/175 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs771805307, COSV61481228, COSV61481289; called by muse, mutect2, varscan2
- NKX2-2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV65819166; called by muse, mutect2, varscan2
- NOL4 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as COSV52338669; called by muse, mutect2, varscan2
- NOL8 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100694518, COSV62634132; called by muse, mutect2, varscan2
- NSUN6 | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66031808; called by muse, mutect2, varscan2
- OR4X2 | c.721T>G p.L241V | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV56582177; called by muse, mutect2, varscan2
- OR51E1 | c.902T>A p.I301N | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67809373; called by muse, mutect2, varscan2
- OR5H15 | c.326C>G p.T109S | Missense Mutation (SNP) | VAF 14/339 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.601); catalogued as COSV62947363; called by muse, mutect2
- PAFAH2 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV65339033; called by mutect2, varscan2
- PALM2AKAP2 | c.761C>G p.S254C (on ENST00000374531 / NM_001037293.2; = p.S286C on NM_053016.6) | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV57112267, COSV57128097; called by muse, mutect2, varscan2
- PATJ | c.2705C>A p.S902Y | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV57155594; called by muse, mutect2, varscan2
- PCDHGA5 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV53899339; called by muse, mutect2, varscan2
- PCIF1 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV65026059; called by muse, mutect2, varscan2
- PHKA2 | c.2032C>T p.P678S | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV66052537; called by muse, mutect2, varscan2
- PIK3CG | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as rs370152741; called by muse, mutect2, varscan2
- PKHD1 | c.5671G>A p.E1891K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV61860749; called by muse, mutect2, varscan2
- PKHD1L1 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101005778; called by muse, mutect2
- PNMA8A | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV58135677; called by muse, mutect2, varscan2
- POLR3C | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 46/79 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as COSV61936043; called by muse, mutect2, varscan2
- PPP1CC | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as COSV58582611; called by muse, mutect2, varscan2
- PRADC1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs749300865, COSV57819654; called by muse, mutect2, varscan2
- PRDM5 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as rs1435763293, COSV53355934; called by muse, mutect2, varscan2
- PRKCQ | c.119-1G>A p.X40_splice | Splice Site (SNP) | VAF 18/55 reads (33%) | catalogued as COSV54106252; called by muse, mutect2, varscan2
- PRR5L | c.276C>A p.F92L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.813); catalogued as COSV61120126; called by muse, mutect2, varscan2
- PRRC2C | c.3563G>C p.R1188T (on ENST00000367742; = p.R1186T on NM_015172.4) | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV58900990; called by muse, mutect2, varscan2
- PSD | c.835C>T p.R279* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as rs1428274929, COSV99192282; called by muse, mutect2, varscan2
- PSIP1 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 20/39 reads (51%) | catalogued as COSV101050915, COSV66253623; called by muse, mutect2, varscan2
- PSME4 | c.4705C>G p.Q1569E | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as COSV66363135, COSV66364667; called by muse, mutect2, varscan2
- RAB3B | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs749171582, COSV100862509, COSV65433482; called by muse, mutect2, varscan2
- RIC3 | c.500G>A p.R167K | Missense Mutation (SNP) | VAF 70/83 reads (84%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.99); catalogued as COSV58300284; called by muse, mutect2, varscan2
- RTTN | c.5236C>G p.L1746V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV55341388; called by muse, mutect2, varscan2
- RUNX1 | c.206A>G p.N69S (on ENST00000344691 / NM_001001890.3; = p.N96S on NM_001754.5) | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.798); catalogued as rs754168875, COSV55867422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62089097; called by muse, mutect2, varscan2
- SAFB2 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1415097994, COSV53040636; called by muse, mutect2, varscan2
- SCN4A | c.3145G>A p.A1049T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV71125617; called by muse, mutect2, varscan2
- SEL1L | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV60919024; called by muse, mutect2, varscan2
- SEMA6A | c.106A>G p.K36E | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.217); catalogued as COSV57307187; called by muse, mutect2, varscan2
- SHANK2 | c.5146G>C p.E1716Q | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV53585925, COSV99571432; called by muse, mutect2, varscan2
- SIRPD | c.303del p.T102Pfs*17 | Frame Shift Del (DEL) | VAF 26/106 reads (25%) | catalogued as rs1273697657; called by mutect2, pindel, varscan2
- SLC19A3 | c.909G>T p.W303C | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51451328; called by muse, mutect2, varscan2
- SLC22A13 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61290225; called by muse, mutect2, varscan2
- SLC24A1 | c.2794G>T p.E932* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs748399766, COSV99978142; called by muse, mutect2, varscan2
- SPEF2 | c.1221G>C p.K407N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV56794864; called by muse, mutect2, varscan2
- SRSF4 | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs776337563, COSV65694067; called by muse, mutect2, varscan2
- SSTR1 | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.117); catalogued as COSV57454957; called by muse, mutect2, varscan2
- STON1 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs1456738136, COSV59126200; called by muse, mutect2, varscan2
- STYXL2 | c.2562C>A p.Y854* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV54805525; called by muse, mutect2, varscan2
- SYNE1 | c.9685C>T p.Q3229* (on ENST00000367255 / NM_182961.4; = p.Q3236* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 18/33 reads (55%) | catalogued as COSV99557951; called by muse, mutect2, varscan2
- TAAR6 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV51582642; called by muse, mutect2, varscan2
- TBX15 | c.880G>A p.D294N (on ENST00000369429 / NM_001330677.2; = p.D188N on NM_152380.3) | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV52867538; called by muse, mutect2, varscan2
- TEX15 | c.6699G>A p.M2233I (on ENST00000256246; = p.M2616I on NM_001350162.2) | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56341653; called by muse, mutect2, varscan2
- TLN1 | c.3365G>A p.R1122Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.284); catalogued as rs763888196, COSV59204120, COSV59209577; called by muse, mutect2, varscan2
- TNS2 | c.823G>C p.E275Q (on ENST00000314250 / NM_170754.4; = p.E285Q on NM_015319.2) | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as COSV58574773; called by muse, mutect2, varscan2
- TNS2 | c.887G>C p.R296T (on ENST00000314250 / NM_170754.4; = p.R306T on NM_015319.2) | Missense Mutation (SNP) | VAF 166/204 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV58574792; called by muse, mutect2, varscan2
- TRDMT1 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1268292915, COSV100003935, COSV58318386; called by muse, mutect2, varscan2
- TRIM21 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.132); catalogued as rs776665896, COSV54342462; called by muse, mutect2, varscan2
- TRIP4 | c.1106A>T p.D369V | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.08); PolyPhen benign (0.113); catalogued as COSV56029662; called by muse, mutect2, varscan2
- TRPM4 | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1466930354, COSV53260229; called by muse, mutect2, varscan2
- TTC31 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 79/155 reads (51%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.025); catalogued as COSV51776086; called by muse, mutect2, varscan2
- TTN | c.94021G>T p.E31341* (on ENST00000591111; = p.E23917* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100602168; called by muse, mutect2, varscan2
- TTN | c.46709G>T p.G15570V (on ENST00000591111; = p.G8146V on NM_003319.4) | Missense Mutation (SNP) | VAF 34/366 reads (9%) | PolyPhen probably damaging (0.925); catalogued as rs1447802224, COSV59890547; called by muse, mutect2
- ULK2 | c.2567C>G p.S856C | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV64444194; called by muse, varscan2
- UNC13A | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV53188456; called by muse, mutect2, varscan2
- USF3 | c.3257C>T p.S1086F | Missense Mutation (SNP) | VAF 94/143 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57069863; called by muse, mutect2, varscan2
- USP10 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.355); catalogued as COSV54746981; called by muse, mutect2, varscan2
- VPS35L | c.2389C>G p.L797V | Missense Mutation (SNP) | VAF 81/140 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV51977245; called by muse, mutect2, varscan2
- WBP2NL | c.69G>C p.L23F | Missense Mutation (SNP) | VAF 65/78 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV60918369; called by muse, mutect2, varscan2
- WDR25 | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs952610374, COSV58933900; called by muse, mutect2, varscan2
- WDR3 | c.1700C>G p.S567C | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as rs1351481129, COSV60452881; called by muse, mutect2, varscan2
- WWC3 | c.2998G>C p.A1000P | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.27); PolyPhen benign (0.179); catalogued as COSV101081233; called by muse, varscan2
- ZFAND5 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 27/92 reads (29%) | catalogued as COSV52988291, COSV99428532; called by muse, mutect2, varscan2
- ZMIZ1 | c.2155T>G p.S719A | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as COSV57889770; called by muse, mutect2, varscan2
- ZNF274 | c.304G>A p.E102K (on ENST00000610905; = p.E70K on NM_016325.3) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1227483813, COSV100464889; called by muse, mutect2
- ZNF33A | c.2275C>G p.Q759E (on ENST00000458705 / NM_006974.3; = p.Q760E on NM_006954.2) | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV56723033, COSV56725140; called by muse, mutect2, varscan2
- ZNF608 | c.3754C>G p.L1252V | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.986); catalogued as COSV60435305; called by muse, mutect2, varscan2
- ZNF829 | c.1255A>C p.S419R | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV66985660; called by muse, mutect2, varscan2
- ZNF831 | c.1990G>T p.A664S | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs1307729124, COSV64037405; called by muse, mutect2, varscan2
- GMPS | c.1044del p.N349Mfs*3 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- TRAV8-7 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- ABCB11 | c.2298G>C p.G766= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV55585478; called by muse, mutect2, varscan2
- ABCC5 | c.4174C>T p.L1392= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV55587169, COSV55590533; called by muse, mutect2, varscan2
- ADGRV1 | c.14193G>A p.V4731= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs377647718; called by muse, mutect2, varscan2
- ARFGEF3 | c.381A>T p.T127= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV52450250; called by muse, mutect2, varscan2
- ATOH8 | c.708C>T p.N236= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs1188519545, COSV60399628; called by muse, mutect2, varscan2
- ATP10B | c.1515G>A p.L505= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs951214791, COSV58777715; called by muse, mutect2, varscan2
- CASP8AP2 | c.2592G>A p.V864= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1156240173, COSV99386890; called by muse, mutect2, varscan2
- CATSPER3 | c.276C>T p.S92= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV50945234; called by muse, varscan2
- CCDC8 | c.1616G>A p.*539= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100281960; called by muse, varscan2
- CCDC8 | c.1548G>A p.R516= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV56772226; called by muse, varscan2
- CEP85 | c.1107C>G p.L369= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as rs1357864948, COSV53327084; called by muse, mutect2, varscan2
- CES5A | c.1350C>G p.V450= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as COSV51863634; called by muse, mutect2
- CHRM3 | c.1479C>T p.L493= | Silent (SNP) | VAF 49/95 reads (52%) | catalogued as COSV55080395; called by muse, mutect2, varscan2
- CPSF3 | c.372C>T p.T124= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs761040737, COSV53007861; called by muse, mutect2, varscan2
- CYFIP1 | c.2778C>T p.I926= | Silent (SNP) | VAF 42/53 reads (79%) | catalogued as rs983336626; called by muse, mutect2, varscan2
- CYP7A1 | c.1284C>T p.L428= | Silent (SNP) | VAF 57/271 reads (21%) | catalogued as COSV56962245; called by muse, mutect2, varscan2
- DPEP2 | c.915G>A p.K305= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV52053809; called by muse, mutect2, varscan2
- DPH2 | c.768G>A p.K256= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV52542536; called by muse, mutect2, varscan2
- DTX3 | c.996G>T p.L332= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as COSV54084386; called by muse, mutect2, varscan2
- EP300 | c.4365G>A p.Q1455= | Silent (SNP) | VAF 51/91 reads (56%) | catalogued as COSV54326253, COSV54333390, COSV54337016; called by muse, mutect2, varscan2
- FAAP24 | c.561G>C p.L187= | Silent (SNP) | VAF 41/139 reads (29%) | catalogued as COSV54274921, COSV54286537; called by muse, mutect2, varscan2
- FDXACB1 | c.1255C>T p.L419= | Silent (SNP) | VAF 58/122 reads (48%) | catalogued as COSV52786330; called by muse, mutect2, varscan2
- FIGNL1 | c.330C>T p.F110= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV63553215; called by muse, mutect2, varscan2
- FNDC1 | c.3586C>T p.L1196= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1363894749, COSV51930936; called by muse, mutect2, varscan2
- FOXN1 | c.1878G>A p.T626= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs766240765, COSV56880414; called by muse, mutect2, varscan2
- FTCD | c.534G>A p.A178= | Silent (SNP) | VAF 76/94 reads (81%) | catalogued as rs557774996, COSV52423196; called by muse, mutect2, varscan2
- GPR89B | c.174C>T p.I58= | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs782340036, COSV100032418; called by mutect2, varscan2
- HNF4A | c.1140C>T p.S380= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as rs767934753, COSV57379772, COSV57380872; called by muse, mutect2, varscan2
- HTR4 | c.567C>T p.N189= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1470751867, COSV58789619; called by muse, mutect2, varscan2
- IHH | c.732C>T p.L244= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs747212856, COSV55392713; called by muse, mutect2, varscan2
- IPO4 | c.2844C>T p.L948= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV61015106; called by muse, mutect2, varscan2
- KCNE4 | c.630C>T p.S210= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs763999451, COSV56054032; called by muse, varscan2
- KIF23 | c.330A>C p.T110= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs766423729, COSV52977295; called by muse, mutect2, varscan2
- KLC1 | c.60A>G p.T20= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as rs1340869235, COSV55805888; called by muse, mutect2, varscan2
- LRFN5 | c.30C>T p.L10= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as COSV53243411; called by muse, mutect2, varscan2
- LRGUK | c.1635G>A p.R545= | Silent (SNP) | VAF 38/153 reads (25%) | catalogued as COSV53634138; called by muse, mutect2, varscan2
- LRRC6 | c.1209A>G p.R403= | Silent (SNP) | VAF 47/160 reads (29%) | catalogued as COSV51537952; called by muse, mutect2, varscan2
- MALT1 | c.918C>T p.I306= | Silent (SNP) | VAF 6/114 reads (5%) | catalogued as COSV61934060; called by muse, mutect2
- MBL2 | c.746G>A p.*249= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as COSV100906295; called by muse, mutect2, varscan2
- MED12L | c.4404C>T p.L1468= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as COSV56368635; called by muse, mutect2, varscan2
- MICB | c.696C>T p.P232= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV52855405; called by muse, mutect2, varscan2
- MST1R | c.2979G>C p.L993= | Silent (SNP) | VAF 27/34 reads (79%) | catalogued as rs1214585240, COSV56564587; called by muse, mutect2, varscan2
- MTF2 | c.777C>G p.L259= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100940028, COSV64769520; called by muse, mutect2, varscan2
- MUC16 | c.16455G>A p.L5485= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV67445269; called by muse, mutect2, varscan2
- NETO1 | c.852C>T p.F284= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs1193440713, COSV55001672; called by muse, mutect2, varscan2
- NEU2 | c.153G>C p.L51= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV52091597; called by muse, mutect2
- OR52N2 | c.192C>T p.F64= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as COSV57676134; called by muse, mutect2, varscan2
- PCDHB14 | c.1971G>A p.T657= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as rs782273788, COSV53386509; called by muse, mutect2, varscan2
- PKLR | c.1053G>T p.L351= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV61360401; called by muse, mutect2, varscan2
- PLEKHM3 | c.1848C>T p.F616= | Silent (SNP) | VAF 47/83 reads (57%) | catalogued as COSV66815529; called by muse, mutect2, varscan2
- PNLIPRP2 | c.21C>T p.L7= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs374345074; called by muse, mutect2, varscan2
- PNMT | c.159C>T p.V53= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs762272500, COSV54092364; called by muse, varscan2
- PSKH1 | c.6C>G p.G2= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV52122354; called by muse, mutect2, varscan2
- PTPRU | c.450C>T p.V150= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV60521967; called by muse, mutect2, varscan2
- RNF213 | c.15018G>A p.S5006= | Silent (SNP) | VAF 38/237 reads (16%) | catalogued as rs1485237975, COSV60390300; called by muse, mutect2, varscan2
- RPL24 | c.102G>A p.A34= | Silent (SNP) | VAF 38/133 reads (29%) | catalogued as rs1216705707, COSV67529752; called by muse, mutect2, varscan2
- RRNAD1 | c.537G>A p.V179= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as COSV57459369, COSV57460485; called by muse, mutect2, varscan2
- SETBP1 | c.2472T>C p.S824= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV56313140; called by muse, mutect2, varscan2
- SLC12A5 | c.2019C>T p.L673= (on ENST00000454036 / NM_001134771.2; = p.L650= on NM_020708.5) | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs746329899, COSV54788472, COSV54803297; called by muse, mutect2, varscan2
- SORCS2 | c.3444C>T p.I1148= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs756516584, COSV61163206; called by muse, mutect2, varscan2
- SPINK5 | c.2940C>T p.D980= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs767880893, COSV56248715; called by muse, mutect2, varscan2
- SZT2 | c.10260C>T p.I3420= (on ENST00000634258 / NM_001365999.1; = p.I3363= on NM_015284.4) | Silent (SNP) | VAF 60/104 reads (58%) | catalogued as COSV65094122; called by muse, mutect2, varscan2
- TMEM200A | c.867A>G p.T289= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV51649219; called by muse, mutect2, varscan2
- TNXB | c.7242C>T p.H2414= (on ENST00000647633; = p.H2167= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs780787972, COSV64473550; called by muse, mutect2, varscan2
- TRPM2 | c.1947C>T p.I649= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs755478549, COSV100308987; called by muse, mutect2
- TXNL4A | c.348C>T p.I116= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as rs1445169904, COSV54099118; called by muse, mutect2, varscan2
- UBLCP1 | c.873C>T p.L291= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as rs569124850, COSV57142569; called by muse, mutect2, varscan2
- VPS13D | c.870C>G p.L290= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as COSV62525291; called by muse, mutect2, varscan2
- ZNF346 | c.621G>A p.K207= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV56155461; called by muse, mutect2, varscan2
- ZNF473 | c.21C>T p.T7= | Silent (SNP) | VAF 24/110 reads (22%) | catalogued as COSV54522047; called by muse, mutect2, varscan2
- ZNF547 | c.222C>A p.V74= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV56579426; called by muse, mutect2, varscan2
- ZNF708 | c.504C>T p.F168= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV63606877, COSV63607984; called by muse, mutect2, varscan2
- ABI2 | c.1193-5579C>A | Intron (SNP) | VAF 59/116 reads (51%) | catalogued as COSV53689891; called by muse, mutect2, varscan2
- BRD4 | c.2158+416C>T | Intron (SNP) | VAF 27/46 reads (59%) | catalogued as COSV54582334; called by muse, mutect2, varscan2
- C9orf163 | n.1238G>T | RNA (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- CR1 | c.487+15239C>A | Intron (SNP) | VAF 15/60 reads (25%) | catalogued as rs1403838676, COSV100887475; called by muse, mutect2, varscan2
- DCHS2 | n.5181G>A | RNA (SNP) | VAF 36/63 reads (57%) | catalogued as COSV61768065; called by muse, mutect2, varscan2
- DCHS2 | n.5180A>T | RNA (SNP) | VAF 34/61 reads (56%) | catalogued as COSV61768071; called by muse, mutect2, varscan2
- FBXL21P | n.600C>A | RNA (SNP) | VAF 46/130 reads (35%) | catalogued as COSV51810137, COSV99778251; called by muse, mutect2, varscan2
- IGKV1-13 | n.171G>A | RNA (SNP) | VAF 113/148 reads (76%) | catalogued as rs754486073; called by muse, mutect2, varscan2
- OBSCN | c.4585+2806G>A | Intron (SNP) | VAF 18/88 reads (20%) | catalogued as COSV52740332; called by muse, mutect2, varscan2
- RCC1 | c.73+607C>T | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as rs1392767066, COSV65778909; called by muse, mutect2, varscan2
- TUBD1 | c.*2C>G | 3'UTR (SNP) | VAF 32/98 reads (33%) | catalogued as COSV100360028; called by muse, mutect2, varscan2
